Surgical pathology report (de-identified scan), TCGA case TCGA-FR-A7UA, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of North Carolina, specimen TCGA-FR-A7UA-06A (Metastatic).

DERMATOPATHOLOGY

Case Number :

100-0-3
Melanoma NOS 872013
Site: Lymph node, axilla
C77.3
9/25/14

Diagnosis:

A: Lymph nodes, right axilla, level 3, dissection
-No evidence of melanoma in 6 lymph nodes (0/6)

B: Lymph nodes, right axilla, dissection
-Metastatic melanoma involving 2 out of 50 lymph nodes, with the largest diameter measuring approximately 4 cm (2/50)
-Extracapsular extension is present

Clinical History:

-year-old female with metastatic melanoma

Gross Description:

A: The specimen was received labeled with the patient' s name and measured 40 x 30 x 8 mm in aggregate. The tissue is entirely submitted as A1-A6,

B: The specimen was received labeled with the patient' s name and measured 10 x 8 x 5 cm. The largest nodes measure 40 x 35 x 20 mm (blocks B17-18) and 30 x 20 x 20 mm (blocks B19-20). The fibrofatty specimen is serially sectioned and then placed in . Lymph node candidates are identified and submitted as B1-B21. Tissue remains in formalin.

Source: NCI Genomic Data Commons file 37b3b25a-d2ca-4a6b-8b03-412df12c44b5 (TCGA-FR-A7UA.94F1943A-F7EA-4A1D-AB04-2ABC80C23B8B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).